Somatic mutation profile of tumor specimen TCGA-AZ-4616-01A (aliquot TCGA-AZ-4616-01A-21D-1835-10) from TCGA case TCGA-AZ-4616, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cecum; AJCC pathologic stage: Stage IV; Age at diagnosis: 82.3 years (30,043 days).
Specimen TCGA-AZ-4616-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b5e17cd3-950b-4bf5-863b-936f5fb10f42.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AZ-4616-10A (Blood Derived Normal), aliquot TCGA-AZ-4616-10A-01D-1835-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/39495aca-acc5-417a-8679-22e9246e77c0

The open-access MAF lists 100 somatic variants for this specimen: 74 protein-altering or splice-affecting, 24 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 63, Silent 24, Nonsense Mutation 5, Frame Shift Ins 3, Splice Site 2, Frame Shift Del 1, Intron 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.2626C>T p.R876* | Nonsense Mutation (SNP) | VAF 8/21 reads (38%) | hotspot (GDC flag); catalogued as rs121913333, CM942020, COSV57320538; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>C p.G12A | Missense Mutation (SNP) | VAF 27/68 reads (40%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.723); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- PIK3CA | c.1637A>G p.Q546R | Missense Mutation (SNP) | VAF 50/116 reads (43%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.934); catalogued as rs397517201, COSV55875400, COSV55876869, COSV55877455; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SMAD4 | c.1256G>T p.G419V | Missense Mutation (SNP) | VAF 15/23 reads (65%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as COSV61685351, COSV61686692; called by muse, mutect2, varscan2
- A2M | c.526G>A p.A176T | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.025); catalogued as rs774076635, COSV59382509; called by muse, mutect2, varscan2
- ABCA4 | c.4177G>T p.V1393F | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.021); catalogued as CM117263, COSV100933026; called by muse, mutect2, varscan2
- ADAMTS7 | c.1088C>T p.A363V | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.091); catalogued as rs775030117, COSV66306264; called by muse, mutect2, varscan2
- ADAMTSL3 | c.3497dup p.N1166Kfs*26 | Frame Shift Ins (INS) | VAF 7/25 reads (28%) | catalogued as rs1567281568; called by mutect2, pindel, varscan2
- ADCYAP1R1 | c.332T>C p.M111T | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs761532830, COSV58442142; called by mutect2, varscan2
- ADGRV1 | c.9785T>C p.F3262S | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.122); catalogued as COSV101315510; called by muse, mutect2, varscan2
- AMER1 | c.1876C>T p.R626* | Nonsense Mutation (SNP) | VAF 6/20 reads (30%) | catalogued as rs1408150272, COSV57655083; called by muse, mutect2, varscan2
- AMPD1 | c.2282G>A p.R761H | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs142643298; called by muse, mutect2, varscan2
- AP3D1 | c.2473G>A p.E825K | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT tolerated (0.45); PolyPhen benign (0.403); catalogued as rs758630548, COSV61425341; called by muse, mutect2, varscan2
- APC | c.688C>A p.R230S | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.194); catalogued as COSV57325373, COSV57365922, COSV99965333; called by mutect2, varscan2
- APC | c.4653_4656del p.E1552Qfs*12 | Frame Shift Del (DEL) | VAF 16/49 reads (33%) | catalogued as COSV57331121; called by mutect2, pindel, varscan2
- ARID1A | c.5269G>C p.A1757P | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0.091); catalogued as COSV100250362; called by muse, mutect2, varscan2
- ATP8B4 | c.3539C>T p.T1180I | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.013); catalogued as COSV99463770; called by mutect2, varscan2
- BFSP1 | c.393C>G p.C131W | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64899623; called by muse, mutect2, varscan2
- C12orf29 | c.692C>A p.S231* | Nonsense Mutation (SNP) | VAF 24/54 reads (44%) | catalogued as COSV58349662; called by muse, mutect2, varscan2
- CAPSL | c.35C>T p.A12V | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as rs770162293, COSV68437415; called by mutect2, varscan2
- CASK | c.1868A>C p.Y623S | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59363211; called by muse, mutect2, varscan2
- CD207 | c.169G>A p.V57I | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs781939546, COSV69651807; called by muse, mutect2, varscan2
- CDC42BPA | c.2893G>A p.D965N | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.71); catalogued as COSV62004755; called by muse, mutect2, varscan2
- CLDN17 | c.638C>T p.T213M | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs781665299, COSV54522109, COSV99729551; called by muse, mutect2, varscan2
- CNGA3 | c.778G>A p.D260N | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs374258471, CM014536, COSV55626007, COSV55629033; called by muse, mutect2, varscan2
- CNKSR1 | c.1440C>A p.F480L (on ENST00000374253 / NM_001297647.2; = p.F473L on NM_006314.3) | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100128203; called by muse, mutect2, varscan2
- CR1 | c.3806G>A p.R1269H | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT tolerated (0.36); PolyPhen benign (0.081); catalogued as rs369632766; called by muse, mutect2, varscan2
- DECR2 | c.364G>A p.A122T | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.987); catalogued as rs74944003; called by muse, mutect2, varscan2
- DNAAF6 | c.140C>A p.S47Y | Missense Mutation (SNP) | VAF 26/100 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV60495351; called by muse, mutect2, varscan2
- EPS8L2 | c.706C>T p.R236C | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.332); catalogued as COSV59347156; called by muse, varscan2
- ERBB4 | c.341G>A p.R114Q | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.987); catalogued as rs767277487, COSV53533522; called by muse, mutect2, varscan2
- ETV5 | c.1311+1G>C p.X437_splice | Splice Site (SNP) | VAF 20/45 reads (44%) | catalogued as COSV60500309; called by muse, mutect2, varscan2
- FKBP15 | c.1099C>T p.R367W | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs745882177, COSV53032632; called by mutect2, varscan2
- FOXP1 | c.1030C>T p.Q344* | Nonsense Mutation (SNP) | VAF 12/32 reads (38%) | catalogued as COSV59536639; called by muse, mutect2, varscan2
- FSCB | c.644G>A p.R215K | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT tolerated (0.33); PolyPhen benign (0.035); catalogued as COSV61217041; called by muse, mutect2, varscan2
- GRID2 | c.1780C>T p.R594* | Nonsense Mutation (SNP) | VAF 9/47 reads (19%) | catalogued as COSV56181925, COSV99944281; called by muse, mutect2, varscan2
- HCN1 | c.2629A>T p.T877S | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.079); catalogued as COSV57497955, COSV57543768; called by muse, mutect2, varscan2
- IFNLR1 | c.1496G>T p.W499L | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.656); catalogued as COSV100551977; called by muse, mutect2
- KCNQ3 | c.989G>A p.R330H | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1162306056, CM149415, CM151633, COSV66465614; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KIF1B | c.1958C>G p.P653R (on ENST00000377086 / NM_001365952.1; = p.P607R on NM_015074.3) | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV99822153, COSV99822475; called by muse, mutect2
- KLK15 | c.271C>T p.R91W | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.848); catalogued as rs1326706289, COSV56825765; called by muse, mutect2, varscan2
- LRIT2 | c.1616G>A p.G539E | Missense Mutation (SNP) | VAF 52/117 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60560321; called by muse, mutect2, varscan2
- MAGI2 | c.2515C>T p.R839C | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs769012473, COSV62639767; called by muse, mutect2, varscan2
- MFSD6 | c.586C>T p.R196C | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.614); catalogued as rs913751558, COSV55621533; called by muse, mutect2, varscan2
- MICU1 | c.451G>T p.D151Y | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100741628; called by muse, mutect2, varscan2
- MTCP1 | c.290A>G p.Q97R | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV62898679; called by muse, mutect2
- MXRA5 | c.6610G>T p.G2204W | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54227532; called by muse, mutect2, varscan2
- NBAS | c.1894G>A p.E632K | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.115); catalogued as COSV99867273; called by muse, mutect2, varscan2
- NOC2L | c.698+1G>T p.X233_splice | Splice Site (SNP) | VAF 6/13 reads (46%) | catalogued as COSV58531112; called by muse, mutect2, varscan2
- OPLAH | c.2093A>G p.N698S | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.293); catalogued as COSV101470726; called by muse, mutect2, varscan2
- OR2T2 | c.706C>T p.R236C | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.729); catalogued as rs200389028, COSV100737564; called by muse, mutect2, varscan2
- PARD3B | c.2140G>C p.V714L | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.047); catalogued as COSV62505309, COSV62520863; called by muse, mutect2, varscan2
- PCDHB8 | c.2381T>G p.F794C | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.713); catalogued as COSV50756504; called by muse, mutect2, varscan2
- PCDHGB3 | c.172G>A p.V58M | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.298); catalogued as rs1435194391, COSV53910636; called by muse, mutect2, varscan2
- PEX5L | c.557G>A p.R186Q | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as rs143237596; called by muse, mutect2, varscan2
- POSTN | c.1417A>G p.M473V | Missense Mutation (SNP) | VAF 37/70 reads (53%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.771); catalogued as COSV65712163; called by muse, mutect2, varscan2
- PRDM10 | c.989C>G p.A330G | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.98); catalogued as COSV100456565; called by muse, mutect2, varscan2
- PRKD3 | c.674C>T p.P225L | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as COSV99305728; called by muse, mutect2, varscan2
- RAB11FIP1 | c.3409G>A p.G1137S | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.527); catalogued as rs1188699711, COSV54761439, COSV54764257; called by muse, mutect2
- RBM46 | c.818A>G p.Y273C | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); catalogued as COSV55977570; called by muse, mutect2, varscan2
- RHOXF2B | c.322G>A p.D108N | Missense Mutation (SNP) | VAF 40/97 reads (41%) | SIFT tolerated (0.41); PolyPhen benign (0.069); catalogued as COSV101003940; called by muse, mutect2, varscan2
- RSF1 | c.2424A>C p.E808D | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as COSV100406898; called by muse, mutect2
- SCPEP1 | c.1150C>T p.R384W | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs771883135, COSV51854990; called by muse, mutect2, varscan2
- SF3B3 | c.2401G>A p.E801K | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.521); catalogued as COSV56785909; called by muse, mutect2, varscan2
- SYT14 | c.169G>A p.G57R | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.302); catalogued as rs757948488, COSV55049423; called by muse, mutect2, varscan2
- TCEAL1 | c.151G>C p.E51Q | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated, low confidence (0.16); PolyPhen possibly damaging (0.624); catalogued as rs1187653939, COSV101010099, COSV65461283; called by muse, varscan2
- TENT5D | c.372T>A p.D124E | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as COSV57635617; called by muse, mutect2, varscan2
- TNS2 | c.1259T>G p.F420C (on ENST00000314250 / NM_170754.4; = p.F430C on NM_015319.2) | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV100047467; called by muse, mutect2, varscan2
- TP53 | c.720T>G p.S240R | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764342812, COSV52783209, COSV52795438, COSV52891634, COSV53135249; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- WIPF2 | c.238G>T p.A80S | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated (0.41); PolyPhen benign (0.029); catalogued as COSV60272760; called by muse, mutect2, varscan2
- ZNF451 | c.2777C>T p.P926L (on ENST00000370706 / NM_001031623.3; = p.P878L on NM_015555.2) | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs548892859, COSV100674995, COSV62596414; called by muse, mutect2, varscan2
- SLC10A4 | c.802G>A p.V268I | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.42); PolyPhen benign (0.017); called by muse, mutect2
- TPP2 | c.347dup p.N116Kfs*4 | Frame Shift Ins (INS) | VAF 6/34 reads (18%) | called by pindel, varscan2
- ZGRF1 | c.6285dup p.E2096Rfs*4 | Frame Shift Ins (INS) | VAF 43/168 reads (26%) | called by mutect2, pindel, varscan2
- AC231657.3 | c.759G>A p.S253= | Silent (SNP) | VAF 10/32 reads (31%) | called by muse, mutect2
- ACSBG1 | c.1758C>T p.A586= | Silent (SNP) | VAF 5/19 reads (26%) | catalogued as rs375037443; called by muse, mutect2, varscan2
- AMELX | c.459G>A p.P153= | Silent (SNP) | VAF 7/45 reads (16%) | catalogued as rs201127558, COSV61635275; called by muse, mutect2, varscan2
- AQR | c.3582T>C p.N1194= | Silent (SNP) | VAF 6/25 reads (24%) | catalogued as COSV99333232; called by muse, mutect2
- CCM2 | c.678C>T p.I226= | Silent (SNP) | VAF 11/31 reads (35%) | catalogued as rs762389537, COSV51847106; called by muse, mutect2, varscan2
- CUX1 | c.3669C>T p.C1223= | Silent (SNP) | VAF 4/19 reads (21%) | catalogued as rs782763250, COSV52907125; called by muse, mutect2, varscan2
- DOCK8 | c.1098G>A p.T366= | Silent (SNP) | VAF 7/51 reads (14%) | catalogued as rs139297216, COSV101210329; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- DSCAML1 | c.4074C>T p.T1358= (on ENST00000321322; = p.T1298= on NM_020693.4) | Silent (SNP) | VAF 8/31 reads (26%) | catalogued as rs761952815, COSV58384383; called by muse, mutect2, varscan2
- ELF4 | c.765A>G p.K255= | Silent (SNP) | VAF 13/75 reads (17%) | catalogued as COSV100257146; called by muse, mutect2, varscan2
- ESRRG | c.309C>T p.D103= | Silent (SNP) | VAF 9/34 reads (26%) | catalogued as COSV63152399; called by muse, mutect2, varscan2
- FCHO2 | c.481A>C p.R161= | Silent (SNP) | VAF 39/95 reads (41%) | catalogued as COSV55106570; called by muse, mutect2, varscan2
- FLT4 | c.312C>T p.N104= | Silent (SNP) | VAF 23/65 reads (35%) | catalogued as rs757182081, COSV56101339; called by muse, mutect2, varscan2
- GPI | c.861C>T p.H287= | Silent (SNP) | VAF 11/28 reads (39%) | catalogued as rs371025511; called by muse, mutect2, varscan2
- GPR179 | c.4845A>C p.G1615= (on ENST00000621958; = p.G1614= on NM_001004334.4) | Silent (SNP) | VAF 38/86 reads (44%) | called by muse, mutect2, varscan2
- ISX | c.618G>A p.A206= | Silent (SNP) | VAF 14/29 reads (48%) | catalogued as rs750677233, COSV58085852; called by muse, mutect2, varscan2
- MAGEL2 | c.2430C>A p.A810= | Silent (SNP) | VAF 9/29 reads (31%) | catalogued as COSV100045735; called by muse, mutect2, varscan2
- PCDH19 | c.3258C>T p.A1086= (on ENST00000373034 / NM_001184880.2; = p.A1038= on NM_020766.3) | Silent (SNP) | VAF 10/27 reads (37%) | catalogued as COSV55259044; called by muse, mutect2, varscan2
- PCDHB3 | c.765C>T p.T255= | Silent (SNP) | VAF 6/52 reads (12%) | catalogued as COSV99164182; called by muse, mutect2
- PCDHGA6 | c.66G>A p.T22= | Silent (SNP) | VAF 15/35 reads (43%) | catalogued as COSV53912629; called by muse, mutect2, varscan2
- PHF7 | c.699C>T p.L233= | Silent (SNP) | VAF 5/12 reads (42%) | catalogued as rs774832111, COSV100015275; called by muse, mutect2, varscan2
- RXRG | c.30G>A p.K10= | Silent (SNP) | VAF 13/64 reads (20%) | catalogued as rs369411424; called by muse, mutect2, varscan2
- SNRPN | c.654G>A p.P218= | Silent (SNP) | VAF 22/53 reads (42%) | catalogued as rs1177734347, COSV57594670; called by muse, mutect2, varscan2
- TTN | c.27402C>T p.S9134= (on ENST00000591111; = p.S8207= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 20/88 reads (23%) | catalogued as rs777096848, COSV59930897; called by muse, mutect2, varscan2
- ZIC3 | c.493C>T p.L165= | Silent (SNP) | VAF 5/27 reads (19%) | catalogued as COSV99798339; called by muse, varscan2
- FYN | c.862+477G>A | Intron (SNP) | VAF 39/89 reads (44%) | catalogued as rs528276348, COSV57609539; called by muse, mutect2, varscan2
- MIR510 | n.25C>G | RNA (SNP) | VAF 25/99 reads (25%) | called by muse, mutect2, varscan2
